Somatic mutation profile of tumor specimen TARGET-10-PAPBYM-09A (aliquot TARGET-10-PAPBYM-09A-01D) from TARGET case TARGET-10-PAPBYM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,086 days).
Specimen TARGET-10-PAPBYM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d90bd949-62c2-414e-94a8-98ebc7388e8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPBYM-10A (Blood Derived Normal), aliquot TARGET-10-PAPBYM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06a857a4-548a-4efa-b15c-9d36af5be7bc

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC179 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs536782365; called by muse, mutect2, varscan2
- CHD4 | c.5087-4T>C | Splice Region (SNP) | VAF 25/29 reads (86%) | catalogued as rs745406197; called by muse, mutect2, varscan2
- NTF3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 54/63 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs377132868; called by muse, mutect2, varscan2
- UACA | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 64/183 reads (35%) | catalogued as COSV100537764; called by muse, mutect2, varscan2
- DOT1L | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 64/152 reads (42%) | called by muse, mutect2, varscan2
- KCNT2 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TRAJ29 | p.N2Ffs*? | Missense Mutation (DEL) | VAF 65/72 reads (90%) | called by mutect2, pindel*, varscan2
- ZDHHC11 | c.784+28C>A | Intron (SNP) | VAF 41/189 reads (22%) | called by muse, mutect2, varscan2
- ZDHHC11B | c.784+28C>A | Intron (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
